Somatic mutation profile of tumor specimen TARGET-10-PARLSU-09A (aliquot TARGET-10-PARLSU-09A-01D) from TARGET case TARGET-10-PARLSU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 21.4 years (7,816 days).
Specimen TARGET-10-PARLSU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f23619e-97a5-4c7f-a218-a54b473c82ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLSU-14A (Bone Marrow Normal), aliquot TARGET-10-PARLSU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20ad3eee-0f98-482f-99bf-e2d08c0c7c87

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Intron 2, 3'UTR 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- KCNH2 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs28928905, CM073156, CM097437; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 12/104 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PDE6C | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 5/87 reads (6%) | catalogued as rs1028838062; ClinVar: pathogenic; called by muse, mutect2
- CACNA1E | c.4780C>T p.R1594C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375830903; called by muse, mutect2
- FAM111A | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 112/233 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs150761330; called by muse, mutect2, varscan2
- MAJIN | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs144991253; called by muse, mutect2, varscan2
- MC4R | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs13447332, CM121075, CM990834, COSV55352467; called by muse, mutect2
- NRAS | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54738004, COSV54746465; called by muse, mutect2
- PIEZO1 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs769790310; called by muse, mutect2, varscan2
- RIMS2 | c.1411C>T p.R471W (on ENST00000666250 / NM_001348490.2; = p.R279W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566248680, COSV51698013; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2
- TATDN2 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs372749908; called by muse, mutect2
- EXOC3L1 | c.1041-2A>C p.X347_splice | Splice Site (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2
- FSIP2 | c.11312C>T p.T3771I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031465 GGCATTCACACAG>AGCGGCAAA | Missense Mutation (DEL) | VAF 25/89 reads (28%) | called by pindel, varscan2*
- MYO18B | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- STAM | c.705A>T p.E235D | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CYSLTR1 | c.204A>C p.A68= | Silent (SNP) | VAF 66/196 reads (34%) | catalogued as rs1363872579; called by muse, mutect2, varscan2
- NID1 | c.2385G>A p.G795= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV51614446; called by muse, mutect2, varscan2
- PRDM8 | c.1134G>T p.T378= | Silent (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- GSG1L2 | c.359-43A>T | Intron (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- LSM4 | c.*65G>C | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- YY2 | c.*3A>T | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- ZNF512 | c.31-62_31-61insGG | Intron (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
